Somatic mutation profile of tumor specimen 0DR7Y7 from CCDI case PBCBDU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Gastrointestinal stromal tumor, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 23.1 years (8,446 days).
Specimen 0DR7Y7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d526f1ad-681d-4e74-b124-2679ca4571a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR7YC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dafa58f6-dd5e-4956-8bc0-729804447e3c

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 20/550 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DOCK8 | c.2955C>A p.F985L | Missense Mutation (SNP) | VAF 101/396 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MUC12 | c.15684C>T p.N5228= (on ENST00000379442; = p.N5085= on NM_001164462.1) | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs746174059; called by muse, mutect2, varscan2
- SYMPK | c.-12-47C>T | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as rs575201536; called by mutect2, varscan2
